Somatic mutation profile of tumor specimen 0DF6VE from CCDI case PBBPWU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sex cord-gonadal stromal tumor, mixed forms; Tissue or organ of origin: Ovary; Age at diagnosis: 13.8 years (5,043 days).
Specimen 0DF6VE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69ee9e66-d1e8-4e21-80b9-6f75703458d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DER0P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69d33a69-0783-4bfc-821e-0c6d2165bd5c

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>C p.E1813Q | Missense Mutation (SNP) | VAF 749/982 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- AFF2 | c.2551G>A p.G851S | Missense Mutation (SNP) | VAF 160/583 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV99665166; called by muse, mutect2, varscan2
- ASXL2 | c.1751G>A p.R584K | Missense Mutation (SNP) | VAF 138/429 reads (32%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CDA | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 258/746 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, varscan2
- NKX2-2 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- TTN | c.38693C>T p.T12898I (on ENST00000591111; = p.T5474I on NM_003319.4) | Missense Mutation (SNP) | VAF 163/511 reads (32%) | PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CSMD1 | c.5352C>T p.S1784= (on ENST00000520002; = p.S1783= on NM_033225.6) | Silent (SNP) | VAF 301/781 reads (39%) | catalogued as rs539146933, COSV59324419; called by muse, mutect2, varscan2
- TPTE | c.1422T>C p.D474= (on ENST00000618007 / NM_199261.4; = p.D456= on NM_199259.4) | Silent (SNP) | VAF 186/2705 reads (7%) | catalogued as rs1471172706; called by muse, mutect2
- UNC45B | c.2115C>A p.S705= | Silent (SNP) | VAF 194/525 reads (37%) | catalogued as COSV99268049; called by muse, mutect2, varscan2
- ANKRD52 | c.463-89A>T | Intron (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2
- HS3ST2 | c.-72C>G | 5'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2
